Somatic mutation profile of tumor specimen TCGA-EJ-A7NF-01A (aliquot TCGA-EJ-A7NF-01A-11D-A33T-08) from TCGA case TCGA-EJ-A7NF, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.4 years (20,587 days).
Specimen TCGA-EJ-A7NF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2c998c03-ccf1-48bc-a0ba-6356fd720655.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A7NF-10A (Blood Derived Normal), aliquot TCGA-EJ-A7NF-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d54ad4a1-d970-42cb-a236-ffee040582cd

The open-access MAF lists 22 somatic variants for this specimen: 13 protein-altering or splice-affecting, 8 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 8, In Frame Del 1, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDSN | c.818G>A p.C273Y | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs948077431, COSV99457280; called by muse, mutect2, varscan2
- CSMD1 | c.863A>T p.N288I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101225397; called by muse, mutect2
- CTDSPL2 | c.604A>G p.N202D | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as COSV99527254; called by muse, mutect2, varscan2
- ERGIC3 | c.763T>A p.Y255N | Missense Mutation (SNP) | VAF 48/155 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV99482031; called by muse, mutect2, varscan2
- HTR3B | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99492035; called by muse, mutect2, varscan2
- IQSEC3 | c.2726C>T p.P909L (on ENST00000538872 / NM_001170738.2; = p.P606L on NM_015232.1) | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.698); catalogued as rs782464556, COSV58288564; called by muse, mutect2, varscan2
- OR6B3 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.08); catalogued as rs572554222, COSV100096764, COSV104407788; called by muse, varscan2
- PACS2 | c.287T>C p.F96S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1566930636, COSV100331004; called by muse, mutect2, varscan2
- RSF1 | c.1822G>C p.E608Q | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.63); catalogued as rs1428677038, COSV100408003; called by muse, mutect2, varscan2
- TRANK1 | c.5711G>A p.R1904H | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.549); catalogued as rs191082794; called by muse, mutect2, varscan2
- UTRN | c.1656A>C p.L552F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV100840658; called by muse, mutect2, varscan2
- EBNA1BP2 | c.899_901del p.K300del | In Frame Del (DEL) | VAF 27/72 reads (38%) | called by pindel, varscan2
- TMEM161B | c.958del p.I320Sfs*10 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- ACSBG1 | c.1062C>T p.D354= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as rs745876684, COSV99357315; called by muse, mutect2, varscan2
- ARL16 | c.84G>C p.L28= | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV100230775; called by muse, mutect2, varscan2
- FAM111B | c.1986T>C p.V662= | Silent (SNP) | VAF 10/117 reads (9%) | catalogued as COSV100639369; called by muse, mutect2
- IL1RAPL1 | c.276C>T p.D92= | Silent (SNP) | VAF 35/49 reads (71%) | catalogued as rs771532815, COSV100150635; called by muse, mutect2, varscan2
- KCNG2 | c.1053C>T p.R351= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs745748032, COSV60269775; called by muse, mutect2, varscan2
- PCDHA6 | c.2082G>T p.V694= | Silent (SNP) | VAF 7/136 reads (5%) | catalogued as COSV100971847; called by muse, mutect2
- SOAT2 | c.543G>A p.P181= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as rs151267658; called by muse, varscan2
- USE1 | c.624G>A p.A208= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs146606083; called by muse, mutect2, varscan2
- MAP2 | c.5074-2104T>A | Intron (SNP) | VAF 12/47 reads (26%) | catalogued as COSV99561782; called by muse, mutect2, varscan2
